Somatic mutation profile of tumor specimen MMRF_1834_1_BM_CD138pos (aliquot MMRF_1834_1_BM_CD138pos_T1_KBS5U_L06448) from MMRF case MMRF_1834, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.4 years (23,524 days).
Specimen MMRF_1834_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8151f99d-690d-4b08-a9fb-38bec622492d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1834_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1834_1_PB_Whole_C2_KBS5U_L06492; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1cd9518f-f848-4cc5-88b4-31ee626ff99b

The open-access MAF lists 84 somatic variants for this specimen: 31 protein-altering or splice-affecting, 13 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, 3'UTR 22, Silent 13, Intron 7, 5'UTR 4, RNA 3, Splice Site 2, 3'Flank 2, 5'Flank 2, Frame Shift Del 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 59/131 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CLEC16A | c.2686C>G p.L896V | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.13); catalogued as rs1351462345, COSV99901316; called by muse, mutect2, varscan2
- CPQ | c.355T>A p.S119T | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.638); catalogued as rs1332089160; called by muse, mutect2, varscan2
- FAM83C | c.47C>A p.A16E | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV65584854; called by muse, varscan2
- IGHV2-70 | c.305C>G p.T102R | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs369201986; called by muse, varscan2
- IGKV3-20 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs753252802; called by muse, mutect2, varscan2
- KIF13A | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs377226069; called by muse, mutect2, varscan2
- MTUS1 | c.29T>C p.I10T | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775430705; called by muse, mutect2, varscan2
- MUC2 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 74/239 reads (31%) | SIFT deleterious (0); catalogued as rs1430765139; called by muse, mutect2, varscan2
- NKX1-2 | c.569T>C p.V190A | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1159528423; called by muse, mutect2, varscan2
- OR10W1 | c.52T>C p.S18P | Missense Mutation (SNP) | VAF 100/316 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs758510543; called by muse, mutect2, varscan2
- SERPINE1 | c.779T>C p.I260T | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1404538620; called by muse, mutect2, varscan2
- ZNF835 | c.1399G>A p.V467M | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV73379294; called by muse, mutect2, varscan2
- ANGPT1 | c.1136A>G p.D379G | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CFP | c.228-5C>G | Splice Region (SNP) | VAF 56/103 reads (54%) | called by muse, mutect2, varscan2
- CHN1 | c.901G>A p.G301R | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP4F11 | c.579_602del p.E193_L200del | In Frame Del (DEL) | VAF 16/116 reads (14%) | called by mutect2, pindel
- DDX59 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 116/246 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- EDIL3 | c.196+2T>A p.X66_splice | Splice Site (SNP) | VAF 41/140 reads (29%) | called by muse, mutect2, varscan2
- FMN2 | c.5061-2A>T p.X1687_splice | Splice Site (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- LTB | c.610A>G p.S204G | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- METTL17 | c.181G>C p.V61L | Missense Mutation (SNP) | VAF 103/223 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- OR5F1 | c.28A>G p.T10A | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.294); called by muse, mutect2
- OR6C6 | c.465T>G p.F155L | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PGM2 | c.745_746del p.K249Vfs*12 | Frame Shift Del (DEL) | VAF 22/89 reads (25%) | called by mutect2, pindel, varscan2
- REPS2 | c.1413G>A p.M471I | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SLC9A6 | c.119C>A p.A40E | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SP2 | c.126T>G p.C42W | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- STK10 | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 99/163 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TMEM164 | c.105G>T p.W35C | Missense Mutation (SNP) | VAF 65/99 reads (66%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- TMEM164 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 65/99 reads (66%) | called by muse, mutect2, varscan2
- ASXL3 | c.2421T>C p.T807= | Silent (SNP) | VAF 143/218 reads (66%) | called by muse, mutect2, varscan2
- CARD14 | c.882G>A p.A294= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as rs1346531461, COSV60122225; called by muse, mutect2, varscan2
- CEACAM16 | c.789G>A p.V263= | Silent (SNP) | VAF 42/169 reads (25%) | catalogued as rs1170337984; called by muse, mutect2, varscan2
- EZR | c.402T>C p.F134= | Silent (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- GPR139 | c.765G>A p.A255= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as rs1303527167, COSV58502068; called by muse, mutect2
- IGHV2-70 | c.225T>C p.D75= | Silent (SNP) | VAF 44/46 reads (96%) | catalogued as rs373801344; called by muse, varscan2
- IGHV2-70D | c.282C>T p.T94= | Silent (SNP) | VAF 30/63 reads (48%) | called by muse, varscan2
- ITPR3 | c.1909C>T p.L637= | Silent (SNP) | VAF 108/231 reads (47%) | called by muse, mutect2, varscan2
- NFIL3 | c.888G>A p.K296= | Silent (SNP) | VAF 45/220 reads (20%) | called by muse, mutect2, varscan2
- PKD1L1 | c.1830T>C p.F610= | Silent (SNP) | VAF 39/113 reads (35%) | catalogued as rs772887236; called by muse, mutect2, varscan2
- SACS | c.7383C>A p.L2461= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as rs1419545155; called by muse, mutect2, varscan2
- SLC35C2 | c.126C>T p.F42= | Silent (SNP) | VAF 15/65 reads (23%) | called by muse, varscan2
- TRPM5 | c.702C>T p.P234= | Silent (SNP) | VAF 33/85 reads (39%) | called by muse, mutect2, varscan2
- AC021218.1 | n.1521G>A | RNA (SNP) | VAF 55/146 reads (38%) | called by muse, mutect2, varscan2
- ADAM22 | c.247-13672A>G | Intron (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- ARHGAP28 | c.*2314A>C | 3'UTR (SNP) | VAF 40/125 reads (32%) | called by muse, mutect2, varscan2
- ARHGEF26 | c.*37C>T | 3'UTR (SNP) | VAF 77/298 reads (26%) | catalogued as rs770008176; called by muse, mutect2, varscan2
- CCDC150 | c.1866+497C>T | Intron (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- CCDC81 | chr11:86374850 T>A | 5'Flank (SNP) | VAF 22/89 reads (25%) | called by muse, mutect2, varscan2
- CFAP58 | c.*114G>A | 3'UTR (SNP) | VAF 66/132 reads (50%) | called by muse, mutect2, varscan2
- DTX4 | c.*2059C>G | 3'UTR (SNP) | VAF 27/88 reads (31%) | called by muse, mutect2, varscan2
- EPHA7 | c.-217G>A | 5'UTR (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- FUBP3 | c.*440A>G | 3'UTR (SNP) | VAF 32/132 reads (24%) | called by muse, mutect2, varscan2
- GRM3 | c.-560G>A | 5'UTR (SNP) | VAF 38/153 reads (25%) | called by muse, mutect2, varscan2
- IGKV2-26 | n.180G>C | RNA (SNP) | VAF 32/82 reads (39%) | catalogued as rs569841029; called by muse, mutect2, varscan2
- ILDR1 | c.*475A>T | 3'UTR (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- IRX2 | c.*589T>C | 3'UTR (SNP) | VAF 39/56 reads (70%) | called by muse, mutect2, varscan2
- MIEF1 | c.*1739T>G | 3'UTR (SNP) | VAF 43/84 reads (51%) | called by muse, mutect2, varscan2
- MIR1185-2 | n.50C>T | RNA (SNP) | VAF 60/120 reads (50%) | catalogued as rs760783264; called by muse, mutect2, varscan2
- MSANTD2 | c.511-1171T>G | Intron (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
- NNT | c.*1603G>T | 3'UTR (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- NRG1 | c.700+639C>T | Intron (SNP) | VAF 12/156 reads (8%) | catalogued as rs543706905; called by muse, mutect2
- NSMCE3 | c.*398del | 3'UTR (DEL) | VAF 49/174 reads (28%) | called by mutect2, pindel, varscan2
- OSMR | c.*1904T>C | 3'UTR (SNP) | VAF 38/62 reads (61%) | called by muse, mutect2, varscan2
- PADI1 | c.*762G>A | 3'UTR (SNP) | VAF 27/53 reads (51%) | catalogued as rs1390071391; called by muse, mutect2, varscan2
- PEX19 | c.*56A>T | 3'UTR (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- PIGG | c.*182C>T | 3'UTR (SNP) | VAF 19/82 reads (23%) | called by muse, mutect2, varscan2
- PLD1 | c.*1173G>A | 3'UTR (SNP) | VAF 23/97 reads (24%) | called by muse, mutect2, varscan2
- PLPPR1 | c.*78C>T | 3'UTR (SNP) | VAF 49/218 reads (22%) | called by muse, mutect2, varscan2
- POLR2B | c.-58C>T | 5'UTR (SNP) | VAF 32/138 reads (23%) | called by muse, mutect2, varscan2
- PPP1R21 | c.274-26T>G | Intron (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- RASEF | c.*1154A>G | 3'UTR (SNP) | VAF 75/145 reads (52%) | catalogued as rs1005936124; called by muse, mutect2, varscan2
- RBM22 | c.*953T>G | 3'UTR (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2
- RGS7 | c.*296T>A | 3'UTR (SNP) | VAF 18/66 reads (27%) | catalogued as rs979811894; called by muse, mutect2, varscan2
- RNU6-389P | chr7:55685230 G>A | 5'Flank (SNP) | VAF 39/137 reads (28%) | catalogued as rs1251293102; called by muse, mutect2, varscan2
- SCARA3 | c.*45C>T | 3'UTR (SNP) | VAF 24/49 reads (49%) | catalogued as rs1040361382; called by muse, mutect2, varscan2
- SGCZ | c.*139C>T | 3'UTR (SNP) | VAF 4/95 reads (4%) | catalogued as COSV66023626; called by muse, mutect2
- SLC35C2 | c.-297C>G | 5'UTR (SNP) | VAF 29/120 reads (24%) | called by muse, mutect2, varscan2
- SNRK | c.*508G>A | 3'UTR (SNP) | VAF 71/106 reads (67%) | catalogued as rs1261215529, COSV99939096; called by muse, mutect2, varscan2
- TENM2 | chr5:168263486 del A | 3'Flank (DEL) | VAF 29/84 reads (35%) | catalogued as rs901664671; called by mutect2, varscan2
- TOMM7 | chr7:22812841 A>C | 3'Flank (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- VPS37B | c.111+5885dup | Intron (INS) | VAF 18/26 reads (69%) | catalogued as rs888490142; called by mutect2, varscan2
- ZMYND8 | c.3425-1774A>G | Intron (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
